Somatic mutation profile of tumor specimen TCGA-AZ-6598-01A (aliquot TCGA-AZ-6598-01A-11D-1771-10) from TCGA case TCGA-AZ-6598, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 77.2 years (28,182 days).
Specimen TCGA-AZ-6598-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e114fc0d-cbc4-47f3-9a3a-3d391c24c0ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6598-11A (Solid Tissue Normal), aliquot TCGA-AZ-6598-11A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3283e9e-f3e6-48f0-9042-133fad0f0e1a

The open-access MAF lists 2,822 somatic variants for this specimen: 2,189 protein-altering or splice-affecting, 591 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,442, Silent 591, Frame Shift Del 503, Frame Shift Ins 107, Nonsense Mutation 59, Splice Site 37, Splice Region 24, Intron 20, In Frame Del 14, 3'UTR 7, 3'Flank 7, RNA 4.

Variants (750 of 2,822; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- AC011462.1 | c.219dup p.R74Qfs*11 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 25/82 reads (30%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.640del p.S214Pfs*16 | Frame Shift Del (DEL) | VAF 101/308 reads (33%) | catalogued as rs786204543; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 36/65 reads (55%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 51/206 reads (25%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- C6 | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV54704910, COSV54705322; called by muse, mutect2, varscan2
- CACNA1A | c.3544del p.L1182Sfs*8 | Frame Shift Del (DEL) | VAF 12/148 reads (8%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, pindel
- COL18A1 | c.3918del p.G1307Dfs*17 (on ENST00000359759 / NM_130444.3; = p.G1072Dfs*17 on NM_030582.4) | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DCLRE1C | c.464+1G>A p.X155_splice (on ENST00000378278 / NM_001350965.2; = p.X40_splice on NM_022487.4) | Splice Site (SNP) | VAF 40/89 reads (45%) | catalogued as rs1162344514, CS099252, COSV63184675; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DLD | c.633del p.V212Ffs*12 | Frame Shift Del (DEL) | VAF 107/392 reads (27%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- HNF1A | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 30/126 reads (24%) | catalogued as rs769086289, CM133559, CM971455, COSV57460583, COSV57462128; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- IRAK4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377584435, CM078314; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.13884del p.T4629Pfs*11 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | catalogued as rs886040960; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MPV17 | c.284del p.G95Afs*7 | Frame Shift Del (DEL) | VAF 12/133 reads (9%) | catalogued as rs766160589, CD0910875; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 58/124 reads (47%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- OCA2 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780296175, CM973034, COSV62353027; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SCN4A | c.4442C>A p.A1481D | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs763893717, CM072031, COSV101438662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.438del p.F146Lfs*26 | Frame Shift Del (DEL) | VAF 282/522 reads (54%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by mutect2, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- SYNGAP1 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795331, COSV53384814; ClinVar: likely pathogenic; called by muse, varscan2
- A2M | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 136/232 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as rs1354170298, COSV100589035; called by muse, mutect2, varscan2
- A4GALT | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs750737826, COSV50745285; called by muse, mutect2, varscan2
- ABCA12 | c.5896T>C p.Y1966H (on ENST00000272895 / NM_173076.3; = p.Y1648H on NM_015657.3) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as COSV55969185; called by muse, mutect2, varscan2
- ABCA12 | c.1382G>A p.G461E (on ENST00000272895 / NM_173076.3; = p.G143E on NM_015657.3) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV55969197; called by muse, mutect2, varscan2
- ABCA2 | c.4967C>T p.T1656M (on ENST00000614293; = p.T1626M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs774502181, COSV55800914; called by muse, mutect2, varscan2
- ABCA5 | c.4255G>A p.A1419T | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV67018159; called by muse, mutect2, varscan2
- ABCA5 | c.3234del p.F1078Lfs*6 | Frame Shift Del (DEL) | VAF 76/251 reads (30%) | catalogued as COSV67016962; called by mutect2, pindel, varscan2
- ABCA7 | c.5795G>A p.R1932H | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54034196; called by muse, mutect2, varscan2
- ABCB10 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100748072; called by muse, mutect2
- ABCB5 | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs761794408, COSV68860005; called by muse, mutect2, varscan2
- ABCC11 | c.3083T>C p.L1028P | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62324839; called by muse, mutect2, varscan2
- ABCC3 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs577213087, COSV53326257; called by muse, mutect2, varscan2
- ABCG8 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs754133516, COSV55391570; called by muse, mutect2, varscan2
- ABI3BP | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV52545330; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 82/192 reads (43%) | catalogued as rs749606695; called by mutect2, varscan2
- ABLIM2 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.595); catalogued as rs371040781; called by muse, mutect2, varscan2
- ABT1 | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51292235; called by muse, mutect2, varscan2
- AC008397.2 | c.1438C>A p.L480I | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53208607; called by muse, mutect2, varscan2
- AC013489.1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV51550739; called by muse, mutect2, varscan2
- ACACB | c.6329C>T p.A2110V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58141515; called by muse, mutect2, varscan2
- ACAP1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.537); catalogued as rs767071679, COSV50138819; called by muse, mutect2, varscan2
- ACD | c.1261C>T p.R421C (on ENST00000620338; = p.R332C on NM_022914.3) | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs762262197, COSV54669297; called by muse, mutect2, varscan2
- ACKR3 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs201845893, COSV56022127; called by muse, mutect2, varscan2
- ACLY | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV61251996; called by muse, mutect2, varscan2
- ACOT7 | c.463A>G p.T155A (on ENST00000377855 / NM_181864.3; = p.T145A on NM_007274.4) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV64114718; called by muse, mutect2, varscan2
- ACOXL | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV67737522; called by muse, mutect2, varscan2
- ACTA1 | c.401T>C p.M134T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.062); catalogued as COSV64203816; called by muse, varscan2
- ACTR3B | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV55452042; called by muse, mutect2, varscan2
- ACVR2A | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296122552, COSV54021353; called by muse, mutect2, varscan2
- ADAM15 | c.2309del p.P770Lfs*35 (on ENST00000356955 / NM_207197.3; = p.P770Lfs*52 on NM_207194.3) | Frame Shift Del (DEL) | VAF 74/168 reads (44%) | catalogued as rs758144914; called by mutect2, varscan2
- ADAM17 | c.2082+2T>C p.X694_splice | Splice Site (SNP) | VAF 61/146 reads (42%) | catalogued as COSV60400850; called by muse, mutect2, varscan2
- ADAM8 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as rs539019756, COSV69865072; called by muse, mutect2, varscan2
- ADAM9 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV65946797; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022dup p.N342Efs*2 | Frame Shift Ins (INS) | VAF 22/103 reads (21%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS18 | c.434A>T p.Y145F | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV51420241; called by muse, mutect2, varscan2
- ADAMTS5 | c.1630A>G p.K544E | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV53182516; called by muse, mutect2, varscan2
- ADAMTS5 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1429677844, COSV53182530; called by muse, mutect2, varscan2
- ADAMTS9 | c.451T>C p.F151L | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55786729; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3616G>A p.G1206S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1019877693, COSV65895926; called by muse, mutect2, varscan2
- ADCK2 | c.389G>A p.W130* | Nonsense Mutation (SNP) | VAF 25/136 reads (18%) | catalogued as COSV50782596; called by muse, mutect2, varscan2
- ADCY1 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs368337715; called by muse, mutect2, varscan2
- ADCY3 | c.3163G>A p.G1055R | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206199288, COSV53170526; called by muse, mutect2, varscan2
- ADCY3 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs749288972, COSV53170535; called by muse, mutect2, varscan2
- ADCY3 | c.1243del p.V415Cfs*27 | Frame Shift Del (DEL) | VAF 43/134 reads (32%) | catalogued as COSV53172762; called by mutect2, pindel, varscan2
- ADCY3 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.871); catalogued as rs201922841; called by muse, mutect2, varscan2
- ADCY7 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs927431610, COSV54269343; called by muse, mutect2, varscan2
- ADCY8 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as rs1302992492, COSV53913858, COSV53930456; called by muse, mutect2, varscan2
- ADCY8 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV53919111; called by muse, mutect2, varscan2
- ADGRA3 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); catalogued as rs754833054, COSV51560289; called by muse, mutect2, varscan2
- ADGRB3 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV101001981; called by muse, mutect2, varscan2
- ADGRB3 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs1416953235, COSV65410135, COSV65418179; called by muse, mutect2, varscan2
- ADGRB3 | c.3439C>T p.H1147Y | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53254380; called by muse, mutect2, varscan2
- ADGRG3 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs368017305; called by muse, mutect2, varscan2
- ADGRL1 | c.4142G>A p.R1381Q (on ENST00000340736 / NM_001008701.3; = p.R1376Q on NM_014921.5) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780931458, COSV61564398; called by muse, varscan2
- ADGRL3 | c.2198C>T p.A733V (on ENST00000506720 / NM_001322402.2; = p.A665V on NM_015236.6) | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.743); catalogued as rs768679654, COSV101547182, COSV72231399; called by muse, mutect2, varscan2
- ADGRV1 | c.7112C>T p.A2371V | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV67991432; called by muse, mutect2, varscan2
- ADGRV1 | c.14052G>A p.W4684* | Nonsense Mutation (SNP) | VAF 36/79 reads (46%) | catalogued as COSV101316381, COSV67991433; called by muse, mutect2, varscan2
- ADSS1 | c.1073+1G>A p.X358_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as rs761489014, COSV58272068, COSV58273460; called by muse, mutect2, varscan2
- AGAP3 | c.1279C>T p.P427S (on ENST00000622464; = p.P463S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV68245984; called by muse, mutect2, varscan2
- AGAP4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1327009720, COSV71164763; called by muse, mutect2, varscan2
- AGBL2 | c.2192A>C p.H731P | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54094205; called by muse, mutect2
- AGBL4 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233179501, COSV61894693; called by muse, mutect2, varscan2
- AGFG1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 102/284 reads (36%) | catalogued as rs1447984322, COSV59513720; called by muse, varscan2
- AGO2 | c.2469C>T p.D823= | Splice Region (SNP) | VAF 23/60 reads (38%) | catalogued as rs777138988, COSV55050363; called by muse, mutect2, varscan2
- AGPAT4 | c.351C>T p.G117= | Splice Region (SNP) | VAF 24/81 reads (30%) | catalogued as COSV57248768; called by muse, mutect2, varscan2
- AGT | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1305641349, COSV64185156; called by muse, mutect2, varscan2
- AHCTF1 | c.2746A>G p.T916A (on ENST00000366508; = p.T890A on NM_015446.5) | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV58253133; called by muse, mutect2, varscan2
- AHNAK | c.2619G>A p.W873* | Nonsense Mutation (SNP) | VAF 74/174 reads (43%) | catalogued as COSV57218120; called by muse, mutect2, varscan2
- AHNAK2 | c.4550A>G p.D1517G | Missense Mutation (SNP) | VAF 97/155 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV60923835; called by muse, mutect2, varscan2
- AICDA | c.159C>T p.N53= | Splice Region (SNP) | VAF 32/114 reads (28%) | catalogued as COSV57565481; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs778351035; called by mutect2, varscan2
- AKAP10 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV56732408; called by muse, mutect2, varscan2
- AKAP6 | c.4882C>A p.L1628I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55224845; called by muse, mutect2, varscan2
- AKAP8 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs371961765; called by muse, mutect2, varscan2
- AKIP1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV55149319; called by muse, mutect2, varscan2
- AL121899.2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs375988138; called by muse, mutect2, varscan2
- AL645922.1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs772837862, COSV54959324; called by muse, mutect2, varscan2
- ALB | c.676A>G p.S226G | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as COSV55740596; called by muse, mutect2, varscan2
- ALDH1A3 | c.849dup p.K284Efs*11 | Frame Shift Ins (INS) | VAF 28/176 reads (16%) | catalogued as rs758955164; called by mutect2, varscan2
- ALDH1L2 | c.2576T>G p.V859G | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1194318287; called by muse, varscan2
- ALDH2 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as rs377123780, COSV55669774; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 30/85 reads (35%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALDH3B1 | c.393A>C p.A131= | Splice Region (SNP) | VAF 22/83 reads (27%) | catalogued as COSV99142091; called by muse, mutect2
- ALDH4A1 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51894729; called by muse, mutect2, varscan2
- ALKBH3 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs202134415; called by muse, mutect2, varscan2
- ALOXE3 | c.253A>G p.S85G | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs1434758398, COSV58554987; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 55/160 reads (34%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALS2CL | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775618276, COSV59672782; called by muse, mutect2, varscan2
- ALX4 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61327981; called by muse, mutect2, varscan2
- AMACR | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 113/459 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); catalogued as COSV100163263; called by muse, mutect2, varscan2
- AMDHD1 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57139764; called by muse, mutect2, varscan2
- AMH | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV55556076; called by muse, mutect2, varscan2
- AMIGO3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57538677; called by muse, mutect2, varscan2
- AMMECR1 | c.893del p.R298Lfs*5 | Frame Shift Del (DEL) | VAF 26/43 reads (60%) | catalogued as COSV53319312, COSV99467221; called by mutect2, pindel, varscan2
- AMN | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV54487499; called by muse, varscan2
- AMPD1 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62417551; called by muse, mutect2, varscan2
- AMT | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs749087037, CD983450, COSV56469502; called by muse, mutect2, varscan2
- ANK1 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764822755, COSV55886641, COSV55889527; called by muse, mutect2, varscan2
- ANK1 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs376581087; called by muse, mutect2, varscan2
- ANK3 | c.11155C>T p.R3719C | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs532004139, COSV55048016; called by muse, mutect2, varscan2
- ANK3 | c.3355A>G p.K1119E (on ENST00000280772 / NM_001320874.2; = p.K253E on NM_001149.3) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV55072030; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1398A>T p.E466D | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51854210; called by muse, mutect2, varscan2
- ANKRD22 | c.400-2A>C p.X134_splice | Splice Site (SNP) | VAF 23/100 reads (23%) | catalogued as COSV64237119; called by muse, mutect2, varscan2
- ANKRD28 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs371624017; called by muse, mutect2, varscan2
- ANKRD39 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); catalogued as rs760813409, COSV66813346; called by muse, mutect2, varscan2
- ANKRD50 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV72385406; called by muse, mutect2, varscan2
- ANKRD53 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV55538487; called by muse, mutect2, varscan2
- ANKS6 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747073459, COSV62050205, COSV62052560; called by muse, mutect2, varscan2
- ANO7 | c.392G>T p.R131L (on ENST00000274979; = p.R76L on NM_001001666.4) | Missense Mutation (SNP) | VAF 84/167 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV51475790; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 104/326 reads (32%) | catalogued as rs759218332; called by mutect2, varscan2
- AP1B1 | c.1748A>G p.E583G | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.744); catalogued as rs898894708, COSV100434835; called by muse, mutect2, varscan2
- APBA2 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV67105344; called by muse, mutect2, varscan2
- APOB | c.12741A>C p.Q4247H | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51945297; called by muse, mutect2, varscan2
- APOB | c.4350A>C p.K1450N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.964); catalogued as COSV51928329; called by muse, mutect2
- APOB | c.3129G>T p.K1043N | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV51945313; called by muse, mutect2
- APOL4 | c.376C>T p.L126F (on ENST00000352371 / NM_145660.2; = p.L123F on NM_030643.4) | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV100274203, COSV60654402; called by muse, mutect2, varscan2
- APPBP2 | c.1555G>T p.G519C | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50028310; called by muse, varscan2
- APPL2 | c.1414A>G p.N472D | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV51592416; called by muse, mutect2, varscan2
- APTX | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs746257545, COSV58929793; called by muse, mutect2, varscan2
- AQP10 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs770847978, COSV100270504; called by muse, mutect2, varscan2
- AQP12B | c.284C>T p.S95F (on ENST00000621682; = p.S107F on NM_001102467.2) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1465433396, COSV68184267; called by muse, mutect2
- AQP2 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 105/195 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV52231229; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 72/168 reads (43%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 54/170 reads (32%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARFGEF3 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV52465435; called by muse, mutect2, varscan2
- ARHGAP31 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.058); catalogued as COSV51796775; called by muse, mutect2, varscan2
- ARHGAP36 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 109/150 reads (73%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs368664815, COSV52268214, COSV52270111; called by muse, mutect2, varscan2
- ARHGAP45 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as rs778566096, COSV57434523; called by muse, mutect2, varscan2
- ARHGEF15 | c.36del p.T13Rfs*169 | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | catalogued as rs1338358886; called by mutect2, pindel, varscan2
- ARHGEF5 | c.2819C>A p.P940H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV99283210; called by mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID3B | c.1396A>G p.M466V | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1337621666, COSV60558532; called by muse, mutect2, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 45/116 reads (39%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARL2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1336838890, COSV55861647; called by muse, mutect2, varscan2
- ARL8B | c.150A>G p.I50M | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56579244; called by muse, mutect2
- ARNT | c.2358del p.S788Qfs*21 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as rs745521026; called by mutect2, pindel, varscan2
- ARNTL2 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53827786; called by muse, mutect2, varscan2
- ARPC5 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54172267; called by muse, mutect2, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ART3 | c.814+2T>C p.X272_splice | Splice Site (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100587977; called by muse, mutect2, varscan2
- ART5 | c.679del p.H227Mfs*18 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs748137393; called by mutect2, pindel, varscan2
- ARTN | c.568C>T p.P190S (on ENST00000372354; = p.P198S on NM_057090.2) | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64911976; called by muse, mutect2, varscan2
- ASAP2 | c.2990del p.P997Rfs*55 | Frame Shift Del (DEL) | VAF 60/197 reads (30%) | catalogued as COSV99432242; called by mutect2, pindel, varscan2
- ASH1L | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1470664170, COSV64211446; called by muse, mutect2, varscan2
- ASIC1 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 83/132 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57319393, COSV99948126; called by muse, mutect2, varscan2
- ASXL2 | c.2333del p.P778Qfs*21 | Frame Shift Del (DEL) | VAF 68/153 reads (44%) | catalogued as rs1271466699; called by mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 54/182 reads (30%) | catalogued as rs746676748; called by mutect2, varscan2
- ATAD3A | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs779111850, COSV59234862; called by muse, mutect2, varscan2
- ATF1 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs1482170814, COSV100015994; called by muse, mutect2
- ATG2A | c.5663del p.G1888Afs*2 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as COSV100815511; called by mutect2, pindel
- ATG9A | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs537149923, COSV54698611; called by muse, varscan2
- ATG9A | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs777855989, COSV54692684; called by muse, varscan2
- ATG9B | c.293dup p.T99Nfs*50 | Frame Shift Ins (INS) | VAF 34/148 reads (23%) | catalogued as rs770350293; called by mutect2, varscan2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 36/72 reads (50%) | catalogued as rs1555143544, COSV63112070; called by mutect2, pindel, varscan2
- ATP1A1 | c.2740G>A p.V914M | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV55193103; called by muse, mutect2, varscan2
- ATP1A4 | c.276del p.T93Pfs*48 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs760258351; called by mutect2, pindel, varscan2
- ATP2A1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs908803462, COSV63920560; called by muse, mutect2, varscan2
- ATP2A2 | c.1495A>G p.T499A | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV58046365; called by muse, mutect2
- ATP8B2 | c.3574A>G p.T1192A (on ENST00000672630; = p.T1159A on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63832516; called by muse, mutect2, varscan2
- ATXN2L | c.3004del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as rs771612620; called by mutect2, pindel, varscan2
- AVPR2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs782511391, COSV100509630; called by muse, mutect2
- B3GAT1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs769059991, COSV56999460; called by muse, mutect2, varscan2
- B4GALNT3 | c.2602G>A p.V868M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs539329065, COSV56750182; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as COSV59620972; called by mutect2, varscan2
- BACE1 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57285751; called by muse, mutect2, varscan2
- BANF1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV56463973; called by muse, mutect2, varscan2
- BANK1 | c.1718A>C p.E573A | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV59847000; called by muse, mutect2, varscan2
- BANP | c.1114G>A p.A372T (on ENST00000286122; = p.A341T on NM_017869.4) | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs757034546, COSV53740641; called by muse, mutect2, varscan2
- BAZ1B | c.3911G>A p.R1304H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1554565739, COSV59992219; called by muse, mutect2, varscan2
- BAZ2A | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs763288135, COSV51640787; called by muse, mutect2, varscan2
- BCAM | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs772105916, COSV54303892; called by muse, varscan2
- BCAT2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV54414572; called by muse, mutect2, varscan2
- BCL11A | c.947G>A p.S316N (on ENST00000335712 / NM_001365609.1; = p.S350N on NM_018014.4) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59634257; called by muse, mutect2, varscan2
- BCLAF1 | c.1373del p.N458Ifs*10 | Frame Shift Del (DEL) | VAF 58/155 reads (37%) | catalogued as rs755078065; called by mutect2, pindel, varscan2
- BCOR | c.4865G>T p.G1622V (on ENST00000378444 / NM_001123385.2; = p.G1588V on NM_017745.6) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652943, COSV60714054; called by muse, mutect2, varscan2
- BDP1 | c.5630A>C p.D1877A | Missense Mutation (SNP) | VAF 88/158 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs376316941; called by muse, varscan2
- BEGAIN | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62069593; called by muse, mutect2, varscan2
- BIRC6 | c.4166T>C p.V1389A | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV101428925, COSV70202178; called by muse, mutect2
- BIVM-ERCC5 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as COSV63246404; called by muse, mutect2, varscan2
- BMP1 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.492); catalogued as COSV59244570; called by muse, mutect2, varscan2
- BMP1 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs376781195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs140884062; called by muse, mutect2, varscan2
- BNC2 | c.2405C>A p.A802D | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as COSV66153152; called by muse, mutect2, varscan2
- BOC | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752137890, COSV99849398; called by muse, mutect2, varscan2
- BOP1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056384755; called by muse, mutect2, varscan2
- BRF2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs372281989; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | catalogued as rs746043904; called by mutect2, varscan2
- BRWD3 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs1064796915, COSV64751743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.10718C>T p.A3573V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99609865; called by muse, mutect2, varscan2
- BTBD16 | c.1507T>G p.F503V | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99585290; called by muse, mutect2
- BTBD3 | c.1163G>T p.W388L | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54780543; called by muse, mutect2, varscan2
- BTD | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57729988; called by muse, mutect2, varscan2
- BTN1A1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV55068501; called by muse, mutect2
- BTN2A1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1404295878, COSV57001966; called by muse, mutect2, varscan2
- C10orf88 | c.401dup p.N134Kfs*12 | Frame Shift Ins (INS) | VAF 69/248 reads (28%) | catalogued as rs751388819; called by mutect2, varscan2
- C11orf49 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV53568882; called by muse, mutect2, varscan2
- C11orf87 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745537999, COSV59356808; called by muse, mutect2, varscan2
- C14orf180 | c.135del p.S46Pfs*3 | Frame Shift Del (DEL) | VAF 75/214 reads (35%) | catalogued as rs761345073; called by mutect2, pindel, varscan2
- C17orf78 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1212132198; called by muse, mutect2, varscan2
- C1S | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 110/183 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as rs781887755, COSV61071835; called by muse, mutect2, varscan2
- C1orf105 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62959698; called by muse, mutect2, varscan2
- C1orf115 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV54274257; called by muse, mutect2, varscan2
- C1orf122 | c.268del p.Q90Sfs*42 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs747134922; called by mutect2, pindel
- C3AR1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 94/145 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as rs376269642, COSV50821158; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 50/240 reads (21%) | catalogued as rs372345940; called by mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 77/116 reads (66%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C8orf34 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61388975; called by muse, mutect2, varscan2
- CA3 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53410615; called by muse, mutect2, varscan2
- CA5B | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1329688924, COSV59416355; called by muse, mutect2, varscan2
- CABIN1 | c.5819C>A p.P1940H | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs374113751; called by muse, mutect2, varscan2
- CACNA1B | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs74951550, COSV99499900; called by muse, mutect2, varscan2
- CACNA1C | c.1673del p.T558Rfs*16 | Frame Shift Del (DEL) | VAF 45/102 reads (44%) | catalogued as COSV59751618, COSV59774311; called by pindel, varscan2
- CACNA1C | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768034509, COSV59728042; called by muse, varscan2
- CACNA1C | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775536781, COSV59751679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.6050C>T p.P2017L (on ENST00000350061 / NM_001128840.3; = p.P2037L on NM_000720.4) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs876657749, COSV99860083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1355669731, COSV100705385; called by muse, mutect2, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CACNA2D1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV62387115; called by muse, mutect2, varscan2
- CACNA2D3 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55564226; called by muse, mutect2, varscan2
- CACNA2D4 | c.630del p.T211Pfs*11 | Frame Shift Del (DEL) | VAF 47/250 reads (19%) | catalogued as COSV99766654; called by mutect2, pindel, varscan2
- CACNG4 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 51/113 reads (45%) | catalogued as rs141844181; called by muse, mutect2, varscan2
- CACNG6 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.683); catalogued as rs971738195, COSV99403680; called by muse, mutect2, varscan2
- CACTIN | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1568290119, COSV50269351; called by muse, mutect2, varscan2
- CALCR | c.1306C>T p.R436C (on ENST00000649521 / NM_001164737.2; = p.R420C on NM_001742.4) | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.764); catalogued as rs567560525, COSV64009006, COSV64009049; called by muse, mutect2, varscan2
- CALHM6 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63991687; called by muse, varscan2
- CALML6 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV57070111; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs754747174; called by mutect2, pindel, varscan2
- CAND2 | c.2773G>A p.A925T (on ENST00000456430 / NM_001162499.2; = p.A832T on NM_012298.3) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs774791381, COSV55990577, COSV99929833; called by mutect2, varscan2
- CAPN15 | c.1589G>T p.R530M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV54838310; called by muse, mutect2, varscan2
- CAPN3 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM1513437, COSV100533450; called by muse, varscan2
- CAPN3 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs767106920, CM051870, COSV58824883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN7 | c.379A>C p.T127P | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV53779899; called by muse, mutect2, varscan2
- CARMIL3 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as COSV57727684; called by muse, mutect2, varscan2
- CASK | c.2441C>T p.A814V (on ENST00000378163 / NM_001367721.1; = p.A809V on NM_003688.3) | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100587788; called by muse, varscan2
- CASKIN1 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV58217016; called by muse, mutect2, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CASP5 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV52830512; called by muse, mutect2, varscan2
- CASZ1 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV59739136; called by muse, mutect2, varscan2
- CASZ1 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as rs576863717, COSV59739145; called by muse, mutect2, varscan2
- CAT | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778007071, COSV53812357; called by muse, mutect2, varscan2
- CBLC | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs745556828, COSV54323156; called by muse, mutect2, varscan2
- CBLL2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1351099954, COSV60369335; called by muse, mutect2
- CCAR2 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52385787; called by muse, mutect2, varscan2
- CCDC102B | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60149327; called by muse, mutect2, varscan2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 132/352 reads (38%) | catalogued as rs368765497; called by mutect2, varscan2
- CCDC110 | c.1586del p.N529Ifs*6 | Frame Shift Del (DEL) | VAF 46/99 reads (46%) | catalogued as rs780308749; called by mutect2, varscan2
- CCDC125 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 102/181 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV67288568; called by muse, mutect2, varscan2
- CCDC138 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs773875431, COSV54570213; called by muse, mutect2, varscan2
- CCDC149 | c.267T>C p.A89= | Splice Region (SNP) | VAF 59/134 reads (44%) | catalogued as COSV60880782; called by muse, mutect2, varscan2
- CCDC191 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV55561072, COSV99847101; called by muse, mutect2, varscan2
- CCDC88B | c.2240A>G p.E747G | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV57267370; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as rs773752200; called by mutect2, pindel
- CCDC93 | c.949C>G p.R317G | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60119161, COSV60122319; called by muse, mutect2, varscan2
- CCKBR | c.40G>T p.G14* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV58100535, COSV58103786; called by muse, mutect2, varscan2
- CCL14 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs771441014; called by muse, mutect2, varscan2
- CCL23 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as rs768484405; called by muse, mutect2, varscan2
- CCN5 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs759003113, COSV51937301; called by muse, mutect2, varscan2
- CCNA1 | c.281G>T p.R94M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV55223078; called by muse, mutect2, varscan2
- CCNL1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55820034; called by muse, mutect2, varscan2
- CCNY | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs1366422830, COSV55188539; called by muse, mutect2, varscan2
- CCR5 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV52752419; called by muse, mutect2
- CCR9 | c.168G>A p.W56* (on ENST00000357632 / NM_031200.3; = p.W44* on NM_006641.4) | Nonsense Mutation (SNP) | VAF 86/222 reads (39%) | catalogued as COSV62940575; called by muse, varscan2
- CD226 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs143019865; called by muse, mutect2, varscan2
- CD300E | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV60791203; called by muse, mutect2, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | catalogued as rs760923345; called by mutect2, varscan2
- CD36 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59216783; called by muse, mutect2, varscan2
- CD68 | c.760+1G>A p.X254_splice | Splice Site (SNP) | VAF 19/166 reads (11%) | catalogued as rs776414308, COSV51511683; called by muse, mutect2, varscan2
- CDC42BPB | c.1851G>T p.Q617H | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV63476208, COSV63476496; called by muse, mutect2, varscan2
- CDH19 | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs749665230, COSV50968733; called by muse, varscan2
- CDH19 | c.1841del p.L614* | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs1568168060; called by pindel, varscan2
- CDH23 | c.8377C>T p.R2793W | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749203752, COSV56479562; called by muse, mutect2, varscan2
- CDH4 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1471947800, COSV64667101; called by muse, mutect2, varscan2
- CDH9 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV50362054; called by muse, mutect2, varscan2
- CDK20 | c.955dup p.H319Pfs*4 (on ENST00000325303 / NM_001039803.3; = p.H298Pfs*4 on NM_012119.4) | Frame Shift Ins (INS) | VAF 40/108 reads (37%) | catalogued as rs749463697; called by mutect2, varscan2
- CDON | c.3490G>A p.A1164T | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757589429, COSV54995339; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CDYL | c.313T>C p.Y105H (on ENST00000328908 / NM_001368125.1; = p.Y51H on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59360962; called by muse, mutect2, varscan2
- CELSR1 | c.7442C>T p.A2481V | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.029); catalogued as COSV53095949; called by muse, mutect2, varscan2
- CEMIP | c.2008G>A p.V670M | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs960069773, COSV54997385; called by muse, mutect2, varscan2
- CENPB | c.1312del p.E438Kfs*43 | Frame Shift Del (DEL) | VAF 89/190 reads (47%) | catalogued as rs748211874; called by mutect2, pindel, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 113/327 reads (35%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPF | c.866-2A>G p.X289_splice | Splice Site (SNP) | VAF 27/371 reads (7%) | catalogued as COSV100871977; called by muse, mutect2
- CENPK | c.496del p.M166Cfs*4 | Frame Shift Del (DEL) | VAF 107/231 reads (46%) | catalogued as rs1238965408, COSV54469596; called by mutect2, pindel, varscan2
- CENPP | c.519del p.F173Lfs*46 | Frame Shift Del (DEL) | VAF 114/261 reads (44%) | catalogued as rs750494120; called by mutect2, varscan2
- CEP126 | c.2796del p.L933Yfs*21 | Frame Shift Del (DEL) | VAF 43/122 reads (35%) | catalogued as COSV54828110; called by mutect2, pindel, varscan2
- CEP164 | c.3895G>A p.A1299T | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.156); catalogued as COSV54044316; called by muse, mutect2, varscan2
- CEP170 | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100317897; called by muse, mutect2, varscan2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 61/164 reads (37%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP70 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV53876341, COSV53877247; called by muse, mutect2, varscan2
- CEP72 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs767316211, COSV53795484; called by muse, mutect2, varscan2
- CEP83 | c.1115A>G p.K372R | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100353239; called by muse, mutect2
- CEP85L | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as rs1241409268, COSV63826137; called by muse, mutect2, varscan2
- CETN1 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs750865589, COSV59121901; called by muse, mutect2, varscan2
- CFAP45 | c.844_846del p.E282del | In Frame Del (DEL) | VAF 74/193 reads (38%) | catalogued as rs753806120; called by mutect2, pindel, varscan2
- CGNL1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55572297; called by muse, mutect2, varscan2
- CHCHD5 | c.34T>G p.C12G | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61424658; called by muse, varscan2
- CHD2 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59121734; called by muse, mutect2, varscan2
- CHD2 | c.3440G>A p.G1147D | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV67712508; called by muse, mutect2, varscan2
- CHD5 | c.5660del p.P1887Rfs*14 | Frame Shift Del (DEL) | VAF 68/146 reads (47%) | catalogued as rs928253921; called by mutect2, varscan2
- CHIT1 | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55148635; called by muse, mutect2, varscan2
- CHMP6 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375030925; called by muse, mutect2, varscan2
- CHMP7 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.696); catalogued as COSV100500771; called by muse, varscan2
- CHRD | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52610846; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as rs751548647; called by mutect2, varscan2
- CHTF18 | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs372760513; called by muse, mutect2, varscan2
- CIBAR1 | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100844728; called by muse, mutect2, varscan2
- CIC | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as rs771399534, COSV50599743; called by muse, varscan2
- CILP2 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV52274829; called by muse, mutect2, varscan2
- CITED2 | c.251del p.P84Rfs*63 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs748689446; called by mutect2, pindel
- CIZ1 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV52971030, COSV99477139; called by muse, mutect2
- CIZ1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs150582882; called by muse, mutect2, varscan2
- CLCN7 | c.2028G>T p.Q676H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.44); catalogued as COSV99247646; called by muse, mutect2
- CLCNKA | c.976del p.V326Cfs*23 | Frame Shift Del (DEL) | VAF 43/130 reads (33%) | catalogued as COSV58893135; called by mutect2, pindel, varscan2
- CLCNKB | c.147C>G p.D49E | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.412); catalogued as COSV65161371; called by muse, varscan2
- CLEC14A | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV60563614; called by muse, mutect2, varscan2
- CLIP2 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs782384622, COSV56283268; called by muse, mutect2, varscan2
- CLIP2 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs782208048, COSV56283288; called by muse, mutect2, varscan2
- CLK4 | c.785A>G p.H262R | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV100309111; called by muse, mutect2, varscan2
- CLMP | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs749210141, COSV71650378; called by muse, mutect2, varscan2
- CLNK | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs774916302, COSV57018837; called by muse, mutect2
- CLPP | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1455608268, COSV55537086; called by muse, mutect2, varscan2
- CLSTN1 | c.795G>A p.W265* (on ENST00000377298 / NM_001009566.3; = p.W255* on NM_014944.4) | Nonsense Mutation (SNP) | VAF 55/151 reads (36%) | catalogued as rs775304743, COSV100790761; called by muse, mutect2, varscan2
- CLUH | c.3617G>A p.R1206H (on ENST00000435359; = p.R1245H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV70929595; called by muse, mutect2, varscan2
- CMAS | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57557186; called by muse, mutect2, varscan2
- CMYA5 | c.11009A>G p.E3670G | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs987158301, COSV71408105; called by muse, mutect2, varscan2
- CNDP2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1352458092, COSV60840893; called by muse, mutect2, varscan2
- CNKSR3 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as COSV72161862; called by muse, mutect2, varscan2
- CNOT1 | c.2774T>C p.L925P | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55320336; called by muse, mutect2, varscan2
- CNTFR | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs933732260, COSV63634400; called by muse, varscan2
- CNTN6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV63176547; called by muse, mutect2, varscan2
- CNTNAP5 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs200795882; called by muse, mutect2, varscan2
- COG4 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200052272, COSV60424279; called by muse, mutect2, varscan2
- COG7 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.597); catalogued as COSV56151824; called by muse, mutect2, varscan2
- COG8 | c.1045T>C p.C349R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54743053; called by muse, mutect2, varscan2
- COL12A1 | c.7627G>C p.E2543Q | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs1361188088, COSV59402780; called by muse, mutect2, varscan2
- COL12A1 | c.4561G>A p.V1521M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59402792; called by muse, mutect2, varscan2
- COL24A1 | c.4506C>T p.S1502= | Splice Region (SNP) | VAF 56/154 reads (36%) | catalogued as COSV65310460; called by muse, mutect2, varscan2
- COL27A1 | c.4247G>A p.R1416Q | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.14); catalogued as rs200663129, COSV61921184; called by muse, mutect2, varscan2
- COL27A1 | c.4274T>C p.L1425P | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.564); catalogued as COSV100621338; called by muse, varscan2
- COL27A1 | c.4511C>A p.P1504H | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV61929189; called by muse, mutect2, varscan2
- COL4A5 | c.1779T>C p.P593= | Splice Region (SNP) | VAF 52/126 reads (41%) | catalogued as rs762200621, COSV60367354; called by muse, mutect2, varscan2
- COL5A1 | c.2088+1G>A p.X696_splice | Splice Site (SNP) | VAF 33/86 reads (38%) | catalogued as COSV65672761; called by muse, mutect2, varscan2
- COL6A1 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs1428047738, COSV62614657; called by muse, mutect2, varscan2
- COL6A6 | c.4328G>A p.G1443D | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62027630; called by muse, mutect2, varscan2
- COL7A1 | c.4322del p.P1441Lfs*269 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | catalogued as rs753185460, CD993036, COSV60402854; called by mutect2, pindel, varscan2
- COL7A1 | c.4127del p.P1376Lfs*23 | Frame Shift Del (DEL) | VAF 23/146 reads (16%) | catalogued as rs757976973; called by pindel, varscan2
- COPB2 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV60813431; called by muse, mutect2, varscan2
- COPG1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); catalogued as rs774874304, COSV59112428, COSV59115688; called by muse, mutect2, varscan2
- COQ9 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs763626877, COSV52646780; called by muse, mutect2, varscan2
- COX5B | c.182C>A p.P61Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV51480995; called by muse, mutect2, varscan2
- CPLX2 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV64001616; called by muse, mutect2, varscan2
- CPSF1 | c.4166G>A p.R1389H | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs868909999, COSV58234839; called by muse, mutect2, varscan2
- CPT1C | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1334592224, COSV54921101; called by muse, mutect2, varscan2
- CPXCR1 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); catalogued as COSV52163624; called by muse, mutect2, varscan2
- CPZ | c.613G>A p.A205T (on ENST00000360986 / NM_001014447.3; = p.A194T on NM_003652.3) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV59922276; called by muse, mutect2, varscan2
- CRB2 | c.2279G>A p.G760D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100749745; called by muse, mutect2, varscan2
- CRB2 | c.3640C>A p.L1214M | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV100749746; called by muse, varscan2
- CRHR1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53282876; called by muse, mutect2, varscan2
- CRISP2 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59255330, COSV59255952; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 20/24 reads (83%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYBG3 | c.6486T>A p.D2162E | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV99477501; called by muse, mutect2, varscan2
- CRYGA | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV58017495; called by muse, mutect2, varscan2
- CRYGS | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs747787300, COSV57192779; called by muse, mutect2, varscan2
- CSF2RA | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as rs1263681514, COSV62624341, COSV62625225; called by muse, mutect2
- CSMD2 | c.7976G>T p.G2659V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1048814983, COSV53940195; called by muse, mutect2, varscan2
- CSRNP1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs200794258; called by muse, mutect2, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 53/223 reads (24%) | catalogued as rs756924682; called by mutect2, varscan2
- CSTF2T | c.1624G>T p.G542C | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV58657178; called by muse, mutect2, varscan2
- CTDP1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50006929; called by muse, mutect2, varscan2
- CUL2 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1347538705, COSV66078403, COSV66079131; called by muse, mutect2, varscan2
- CUX2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 137/243 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376298955; called by muse, mutect2, varscan2
- CXCR4 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV54015008; called by muse, varscan2
- CXCR5 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1343378451, COSV52687500; called by muse, mutect2, varscan2
- CYB5RL | c.894A>G p.I298M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55278289; called by muse, mutect2, varscan2
- CYP1A2 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1181238166, COSV59660432; called by muse, mutect2, varscan2
- CYP26A1 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56419332; called by muse, mutect2, varscan2
- CYP46A1 | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55895891; called by muse, mutect2, varscan2
- CYSLTR1 | c.671del p.N224Ifs*9 | Frame Shift Del (DEL) | VAF 52/95 reads (55%) | catalogued as rs766746913; called by mutect2, varscan2
- CYTL1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV57037440; called by muse, varscan2
- CZIB | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53759996; called by muse, mutect2, varscan2
- DAAM2 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs201159453; called by muse, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 33/62 reads (53%) | catalogued as rs751187768; called by mutect2, varscan2
- DACT1 | c.1559del p.P520Rfs*60 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | catalogued as rs1481022066; called by mutect2, pindel, varscan2
- DAPL1 | c.43G>T p.G15* | Nonsense Mutation (SNP) | VAF 50/116 reads (43%) | catalogued as COSV59375526; called by muse, mutect2, varscan2
- DBN1 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV52791564; called by muse, mutect2, varscan2
- DCAF17 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs541750069, COSV59830884; called by muse, mutect2, varscan2
- DCC | c.1898T>C p.V633A | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.656); catalogued as COSV59121753; called by muse, mutect2, varscan2
- DCDC2B | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52210309; called by muse, mutect2
- DCHS1 | c.8665C>T p.R2889W | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs377005527; called by muse, mutect2, varscan2
- DCHS1 | c.6533C>T p.A2178V | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV55039897; called by muse, mutect2, varscan2
- DCHS1 | c.1120dup p.Q374Pfs*4 | Frame Shift Ins (INS) | VAF 21/65 reads (32%) | catalogued as rs1310584543; called by mutect2, pindel, varscan2
- DCLK1 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55211780, COSV55216574, COSV99713109; called by muse, mutect2, varscan2
- DCTN1 | c.2914C>T p.R972W | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756183069, COSV62620652; called by muse, mutect2, varscan2
- DDI1 | c.332A>T p.H111L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV56387194; called by muse, mutect2, varscan2
- DDIAS | c.2094G>T p.Q698H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV100231515, COSV61272824; called by muse, mutect2, varscan2
- DDX1 | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 122/509 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV51841980; called by muse, varscan2
- DDX19A | c.1123A>C p.I375L | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as COSV56360760; called by muse, mutect2, varscan2
- DDX55 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 87/164 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.071); catalogued as COSV53017021; called by muse, mutect2, varscan2
- DEDD | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100919138; called by muse, mutect2, varscan2
- DEDD2 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs376459217; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND2C | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV67923186; called by muse, mutect2, varscan2
- DGAT1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.883); catalogued as COSV60048901; called by muse, mutect2, varscan2
- DGCR8 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV61228076; called by muse, mutect2, varscan2
- DGKA | c.1588-1G>T p.X530_splice | Splice Site (SNP) | VAF 49/147 reads (33%) | catalogued as COSV59387660; called by muse, mutect2, varscan2
- DGKD | c.3332G>A p.R1111H (on ENST00000264057 / NM_152879.3; = p.R1067H on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs559299318, COSV51079496; called by muse, mutect2, varscan2
- DGKI | c.2195G>A p.S732N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV55965818; called by muse, mutect2, varscan2
- DGKI | c.1642+2T>C p.X548_splice | Splice Site (SNP) | VAF 22/35 reads (63%) | catalogued as COSV55962982, COSV99937319; called by muse, mutect2, varscan2
- DGKZ | c.1586A>G p.Y529C (on ENST00000454345 / NM_001105540.2; = p.Y341C on NM_003646.4) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58992640; called by muse, mutect2, varscan2
- DHX30 | c.2699T>C p.L900P (on ENST00000445061 / NM_138615.3; = p.L861P on NM_014966.3) | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53140726; called by muse, mutect2, varscan2
- DHX58 | c.1739T>C p.V580A | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs782221859, COSV52427326; called by muse, mutect2, varscan2
- DICER1 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762784970, COSV58618438; called by muse, mutect2, varscan2
- DIDO1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs372803348; called by muse, mutect2, varscan2
- DIP2A | c.4403G>A p.R1468Q | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1318396418, COSV59482795; called by muse, mutect2, varscan2
- DIRAS2 | c.575T>A p.L192H | Missense Mutation (SNP) | VAF 186/468 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV101005910; called by muse, mutect2, varscan2
- DLC1 | c.2702A>G p.D901G (on ENST00000276297 / NM_001348081.2; = p.D464G on NM_006094.5) | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV52331402; called by muse, mutect2
- DLG4 | c.1951C>T p.R651C (on ENST00000399506 / NM_001321075.3; = p.R694C on NM_001365.4) | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1290892445, COSV57240752; called by muse, mutect2, varscan2
- DLG5 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64949035; called by muse, mutect2, varscan2
- DMBT1 | c.7604dup p.R2536Tfs*79 (on ENST00000338354 / NM_001377530.1; = p.R1779Tfs*79 on NM_004406.3) | Frame Shift Ins (INS) | VAF 27/80 reads (34%) | catalogued as rs758466994; called by mutect2, varscan2
- DNAH10 | c.6547G>A p.V2183I (on ENST00000409039; = p.V2122I on NM_207437.3) | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as rs1317911819, COSV68996400; called by muse, mutect2, varscan2
- DNAH2 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as rs201605458; called by muse, mutect2, varscan2
- DNAH2 | c.13027C>T p.R4343W | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs537433995, COSV66723397; called by muse, mutect2, varscan2
- DNAH3 | c.9959A>G p.Y3320C | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779859457, COSV54538860; called by muse, mutect2, varscan2
- DNAH3 | c.6425A>G p.D2142G | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54538885; called by muse, mutect2, varscan2
- DNAH8 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV59467650; called by muse, mutect2, varscan2
- DNAH8 | c.7316A>T p.N2439I | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV59467687; called by muse, mutect2, varscan2
- DNAH8 | c.10330del p.Q3444Rfs*16 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as rs1561871474, COSV59467705; called by mutect2, pindel, varscan2
- DNAH9 | c.10066G>A p.A3356T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV52365321; called by muse, mutect2, varscan2
- DNAH9 | c.11194G>C p.D3732H | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52365331; called by muse, mutect2, varscan2
- DNAI3 | c.998G>T p.S333I | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV54004717; called by muse, mutect2, varscan2
- DNAJA1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs141132012; called by muse, mutect2, varscan2
- DNAJC21 | c.1247dup p.C417Vfs*21 | Frame Shift Ins (INS) | VAF 58/226 reads (26%) | catalogued as rs1280535851; called by mutect2, pindel, varscan2
- DNAJC22 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs775389117, COSV67712621; called by muse, mutect2, varscan2
- DNAJC7 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57269835; called by muse, mutect2, varscan2
- DNM3 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748395660, COSV62463290; called by muse, mutect2, varscan2
- DOCK8 | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV66618187, COSV66622542; called by muse, mutect2, varscan2
- DONSON | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 47/101 reads (47%) | catalogued as rs753740715, COSV51677039; called by muse, mutect2, varscan2
- DPP6 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.238); catalogued as COSV68057663; called by muse, mutect2, varscan2
- DPP8 | c.2038C>T p.R680W (on ENST00000341861 / NM_001320875.2; = p.R664W on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs761602081, COSV55681404; called by muse, mutect2, varscan2
- DPPA4 | c.179-2A>G p.X60_splice | Splice Site (SNP) | VAF 61/162 reads (38%) | catalogued as rs1305579791, COSV59511875; called by muse, mutect2, varscan2
- DPYD | c.2999A>G p.D1000G | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.94); catalogued as COSV100929422; called by muse, mutect2, varscan2
- DPYD | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145548112; ClinVar: not provided; called by muse, mutect2, varscan2
- DPYSL2 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60781901; called by muse, mutect2, varscan2
- DRD1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV67105012; called by muse, mutect2, varscan2
- DRD2 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV100669587, COSV60760804; called by muse, mutect2, varscan2
- DRP2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 45/65 reads (69%) | catalogued as COSV65811223; called by muse, mutect2, varscan2
- DSC2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142331975, CM108392, COSV51867351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.5186-2A>G p.X1729_splice | Splice Site (SNP) | VAF 38/120 reads (32%) | catalogued as COSV68032372; called by muse, mutect2, varscan2
- DSCAM | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763287823, COSV101261464, COSV68032377; called by muse, mutect2, varscan2
- DSCAML1 | c.3709G>A p.V1237I (on ENST00000321322; = p.V1177I on NM_020693.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs544850403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAML1 | c.1491del p.T498Rfs*33 (on ENST00000321322; = p.T438Rfs*33 on NM_020693.4) | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | catalogued as COSV58386901; called by mutect2, pindel, varscan2
- DSCAML1 | c.434A>G p.Y145C (on ENST00000321322; = p.Y85C on NM_020693.4) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV58398137; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUOX2 | c.2148+2T>C p.X716_splice | Splice Site (SNP) | VAF 55/156 reads (35%) | catalogued as COSV66533391; called by muse, mutect2, varscan2
- DUSP16 | c.890_892del p.K297del | In Frame Del (DEL) | VAF 44/170 reads (26%) | catalogued as rs779051193; called by pindel, varscan2
- DUSP3 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56824306, COSV56825295, COSV56825505; called by muse, mutect2, varscan2
- DVL3 | c.1995del p.M666Cfs*2 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs771967735; called by mutect2, varscan2
- DYM | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780213256, COSV53989333; called by muse, mutect2, varscan2
- DYNC1H1 | c.5124G>T p.E1708D | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV100795411; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1288del p.I430Lfs*5 | Frame Shift Del (DEL) | VAF 60/136 reads (44%) | catalogued as rs748891796; called by mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 59/206 reads (29%) | catalogued as rs751377941; called by mutect2, varscan2
- DYRK3 | c.1400del p.G467Vfs*21 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | catalogued as rs781995280, COSV100895769; called by mutect2, pindel, varscan2
- DYSF | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50504677; called by muse, mutect2, varscan2
- DZANK1 | c.2080G>T p.A694S (on ENST00000262547 / NM_001099407.1; = p.A501S on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.055); catalogued as COSV52749392, COSV52750149; called by muse, mutect2, varscan2
- DZANK1 | c.652del p.R218Gfs*45 (on ENST00000262547 / NM_001099407.1; = p.R19Gfs*45 on NM_018152.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 89/328 reads (27%) | catalogued as rs1568990859; called by mutect2, pindel, varscan2
- DZIP1L | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs754376571, COSV100551697, COSV59522516; called by muse, mutect2, varscan2
- ECE1 | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894874834, COSV51666667, COSV99942556; called by muse, mutect2, varscan2
- EDNRB | c.536C>T p.P179L (on ENST00000377211 / NM_001201397.1; = p.P89L on NM_000115.5) | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57524395; called by muse, mutect2, varscan2
- EEF1E1 | c.375T>A p.H125Q | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101121274; called by muse, varscan2
- EFHD2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV65658194; called by muse, mutect2, varscan2
- EFNB3 | c.836del p.G279Vfs*15 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs1241382696; called by mutect2, pindel, varscan2
- EGR1 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 136/242 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV53520677; called by muse, mutect2, varscan2
- EGR1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV53520685; called by muse, mutect2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 90/210 reads (43%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as COSV99653876; called by mutect2, varscan2
- EGR3 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100416285; called by muse, mutect2, varscan2
- EHHADH | c.2100del p.K700Nfs*10 | Frame Shift Del (DEL) | VAF 55/152 reads (36%) | catalogued as rs747455018; called by mutect2, pindel, varscan2
- EIF4E3 | c.334C>T p.R112* (on ENST00000425534 / NM_001134651.2; = p.R6* on NM_173359.5) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs149437626; called by muse, mutect2, varscan2
- ELOA2 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs777399852, COSV55298449; called by muse, varscan2
- ELP1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.182); catalogued as rs1198964450, COSV101010384, COSV65899010; called by muse, mutect2, varscan2
- ELP1 | c.1750+2T>C p.X584_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as rs988318064, COSV101010502; called by muse, varscan2
- EMILIN1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV66694384; called by muse, mutect2, varscan2
- ENAM | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV68536651; called by muse, mutect2, varscan2
- ENC1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56630551; called by muse, mutect2, varscan2
- ENOSF1 | c.278C>T p.A93V (on ENST00000340116 / NM_001354066.2; = p.A45V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV51894482; called by muse, mutect2, varscan2
- ENTR1 | c.816C>G p.D272E (on ENST00000357365 / NM_001039707.2; = p.D249E on NM_006643.4) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53742589; called by muse, mutect2, varscan2
- EOMES | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs137915789; called by muse, mutect2, varscan2
- EP400 | c.3964C>A p.L1322M | Missense Mutation (SNP) | VAF 166/290 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57780704; called by muse, mutect2, varscan2
- EPB41L3 | c.3213A>T p.K1071N | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59448617, COSV59460416; called by muse, mutect2, varscan2
- EPB41L4A | c.256+2T>C p.X86_splice | Splice Site (SNP) | VAF 71/225 reads (32%) | catalogued as COSV54876025; called by muse, mutect2, varscan2
- EPC1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53924155, COSV53928635; called by muse, mutect2, varscan2
- EPHA5 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs910705978, COSV56652007, COSV56655869; called by muse, mutect2, varscan2
- EPHB3 | c.2582T>C p.M861T | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57807980; called by muse, mutect2, varscan2
- EPHX1 | c.400dup p.Q134Pfs*26 | Frame Shift Ins (INS) | VAF 22/94 reads (23%) | catalogued as rs756407271; called by mutect2, varscan2
- EPN3 | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV52141966; called by muse, mutect2, varscan2
- EPPK1 | c.5741A>G p.H1914R | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV73262072; called by muse, mutect2, varscan2
- EPPK1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs927778676, COSV101599983, COSV73261333; called by muse, mutect2
- EPSTI1 | c.466del p.M156* | Frame Shift Del (DEL) | VAF 47/408 reads (12%) | catalogued as rs781504180; called by mutect2, varscan2
- EPSTI1 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1004498186, COSV58047505; called by muse, mutect2, varscan2
- EPX | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs577707337, COSV56597681; called by muse, mutect2, varscan2
- ERCC2 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as CM1211764, CM970444, COSV67269220; called by muse, mutect2
- ERGIC3 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 105/195 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV53415064; called by muse, mutect2, varscan2
- ERICH1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100033084; called by muse, mutect2, varscan2
- ERICH1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 101/363 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as rs143811367; called by muse, mutect2, varscan2
- ERRFI1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs746056102, COSV66311447; called by muse, mutect2, varscan2
- ERVW-1 | c.149dup p.S51Ifs*3 | Frame Shift Ins (INS) | VAF 19/133 reads (14%) | catalogued as rs750124319; called by mutect2, pindel, varscan2
- ESCO1 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs367553775; called by muse, mutect2, varscan2
- ESRRA | c.775T>C p.S259P | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50007365; called by muse, mutect2, varscan2
- ESYT3 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV56680557; called by muse, mutect2, varscan2
- ETV5 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs767684440, COSV60500669; called by muse, mutect2, varscan2
- EVA1B | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV54635104; called by muse, mutect2, varscan2
- EVI5 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1311854813, COSV64828914; called by muse, mutect2, varscan2
- EVI5 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV64827660; called by muse, varscan2
- EVI5L | c.1876A>C p.S626R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.242); catalogued as COSV99563556; called by muse, mutect2, varscan2
- EVI5L | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV54487574; called by muse, varscan2
- EXOC3L1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52047877; called by muse, mutect2, varscan2
- EXOC6B | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs965938548, COSV55565100; called by muse, mutect2, varscan2
- EXOSC4 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs376508817, COSV60156058; called by muse, mutect2, varscan2
- EYA4 | c.1866G>T p.M622I (on ENST00000531901 / NM_001301013.1; = p.M616I on NM_004100.5) | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV62057787; called by muse, mutect2, varscan2
- F13A1 | c.869del p.P290Hfs*72 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | catalogued as CM103179, COSV53554649; called by mutect2, pindel, varscan2
- F8 | c.4939A>G p.K1647E | Missense Mutation (SNP) | VAF 153/234 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV64276810; called by muse, mutect2, varscan2
- FAAP100 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100585603; called by muse, mutect2, varscan2
- FABP6 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67437461; called by muse, mutect2, varscan2
- FAF2 | c.974T>A p.V325E | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56130379, COSV99990695; called by muse, varscan2
- FAM120B | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs749658778, COSV53006782; called by muse, mutect2, varscan2
- FAM120C | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.006); catalogued as rs1306829749, COSV60261114; called by muse, mutect2
- FAM153A | c.772-2A>C p.X258_splice | Splice Site (SNP) | VAF 311/760 reads (41%) | catalogued as COSV100647124; called by muse, mutect2, varscan2
- FAM153B | c.385G>A p.G129S (on ENST00000253490; = p.G52S on NM_001265615.1) | Missense Mutation (SNP) | VAF 283/839 reads (34%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs908759451, COSV99499150; called by muse, mutect2, varscan2
- FAM181B | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.644); catalogued as COSV61300902; called by muse, mutect2, varscan2
- FAM193A | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as rs1334848571, COSV100219278, COSV61196916; called by muse, mutect2, varscan2
- FAM214A | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV55926068; called by muse, mutect2, varscan2
- FAM3D | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62558939; called by muse, mutect2, varscan2
- FAM71B | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 89/178 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57230145; called by muse, mutect2, varscan2
- FANCI | c.1522A>T p.K508* | Nonsense Mutation (SNP) | VAF 12/218 reads (6%) | catalogued as COSV55531273; called by muse, mutect2
- FAR2 | c.985del p.I329Sfs*49 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs766089727; called by mutect2, pindel, varscan2
- FASTKD1 | c.2378A>G p.H793R | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV52931125; called by muse, mutect2, varscan2
- FASTKD1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748808096, COSV70007072; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 76/297 reads (26%) | catalogued as rs773607911, COSV52947201; called by mutect2, pindel, varscan2
- FAT1 | c.12478C>T p.R4160C | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV71673072; called by muse, mutect2, varscan2
- FAT1 | c.7579G>A p.V2527I | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373112377, COSV71675202; called by muse, mutect2, varscan2
- FAT1 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs750145449, COSV71675304; called by muse, mutect2, varscan2
- FAT4 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV67894837; called by muse, varscan2
- FAT4 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67894840; called by muse, varscan2
- FAT4 | c.7154T>C p.L2385S | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV58699616; called by muse, mutect2, varscan2
- FAT4 | c.10621C>A p.P3541T | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58699632; called by muse, mutect2, varscan2
- FATE1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as rs144817068, COSV64849161; called by muse, mutect2, varscan2
- FBLIM1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs767546555, COSV60030897; called by muse, mutect2, varscan2
- FBLN5 | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV50906364; called by muse, mutect2, varscan2
- FBN1 | c.3382G>T p.V1128F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as CM013926, COSV57325336; called by muse, mutect2, varscan2
- FBXL3 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1383545118, COSV62919116; called by muse, mutect2, varscan2
- FBXO21 | c.1672G>A p.G558S (on ENST00000330622 / NM_033624.3; = p.G551S on NM_015002.3) | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57974311; called by muse, mutect2, varscan2
- FBXO40 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as COSV57526154; called by muse, mutect2, varscan2
- FCMR | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV65567929; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 58/104 reads (56%) | catalogued as rs1288807478; called by mutect2, varscan2
- FCRL5 | c.2564del p.G855Afs*5 | Frame Shift Del (DEL) | VAF 120/329 reads (36%) | catalogued as rs769174325, COSV62519363; called by mutect2, pindel, varscan2
- FDXR | c.964C>T p.R322W (on ENST00000293195 / NM_024417.5; = p.R328W on NM_004110.6) | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs778860222, COSV53116268; called by muse, mutect2, varscan2
- FGD3 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs776061609, COSV61595571; called by muse, mutect2, varscan2
- FGF5 | c.550dup p.T184Nfs*11 | Frame Shift Ins (INS) | VAF 23/158 reads (15%) | catalogued as rs761416300; called by mutect2, pindel, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 83/122 reads (68%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGN | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199883388; called by muse, mutect2, varscan2
- FLCN | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs764899882, COSV53261640; called by muse, mutect2, varscan2
- FLG2 | c.4783C>T p.R1595* | Nonsense Mutation (SNP) | VAF 166/374 reads (44%) | catalogued as rs771013080, COSV66171001; called by muse, mutect2, varscan2
- FLI1 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV55642757; called by muse, mutect2, varscan2
- FLNA | c.5146del p.Q1716Sfs*23 (on ENST00000369850 / NM_001110556.2; = p.Q1708Sfs*23 on NM_001456.3) | Frame Shift Del (DEL) | VAF 79/153 reads (52%) | catalogued as COSV61048769; called by mutect2, pindel, varscan2
- FLNC | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV57960998; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs769482947; called by mutect2, varscan2
- FMN1 | c.3936del p.E1313Sfs*25 (on ENST00000616417 / NM_001277313.2; = p.E1090Sfs*25 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 70/201 reads (35%) | catalogued as rs752560237; called by pindel, varscan2
- FN1 | c.2981C>A p.T994K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV60559375; called by muse, mutect2, varscan2
- FNBP4 | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55450800; called by muse, mutect2, varscan2
- FNDC1 | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV51944064; called by muse, mutect2, varscan2
- FNDC8 | c.71T>C p.M24T | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV50103066; called by muse, mutect2, varscan2
- FNIP1 | c.2623A>G p.T875A | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs766303309, COSV57198785; called by muse, mutect2, varscan2
- FOCAD | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.995); catalogued as rs767440130, COSV58104740; called by muse, mutect2, varscan2
- FOCAD | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs199581066; called by muse, mutect2, varscan2
- FOCAD | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753108162, COSV58094816; called by muse, mutect2, varscan2
- FOSB | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV62279047; called by muse, mutect2, varscan2
- FOXG1 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100487076; called by muse, mutect2, varscan2
- FOXK1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61067208; called by muse, mutect2, varscan2
- FOXM1 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61206960; called by muse, mutect2, varscan2
- FOXM1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs144843550; called by muse, mutect2, varscan2
- FOXO1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 140/520 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs377728010; called by muse, mutect2, varscan2
- FPGS | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV100785312, COSV61228293; called by muse, mutect2, varscan2
- FRAS1 | c.9182C>T p.A3061V | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs886059637, COSV53630192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM1 | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV66533262; called by muse, mutect2, varscan2
- FREM2 | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.017); catalogued as COSV54841174; called by muse, mutect2, varscan2
- FRMD1 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51963956; called by muse, mutect2, varscan2
- FRMD1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs141533034; called by muse, mutect2, varscan2
- FRMD6 | c.1211G>A p.R404Q (on ENST00000344768 / NM_001267046.2; = p.R396Q on NM_152330.4) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.884); catalogued as rs369852661, COSV100655842; called by muse, mutect2, varscan2
- FRMPD1 | c.1105C>A p.L369M | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66701710; called by muse, mutect2, varscan2
- FRS3 | c.67-2A>G p.X23_splice | Splice Site (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99443165; called by muse, mutect2, varscan2
- FRY | c.6629G>A p.R2210Q | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs776871199, COSV66569661; called by muse, varscan2
- FSCN1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378498427, COSV61017522; called by muse, mutect2, varscan2
- FUT1 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs1424903835, COSV59569446; called by muse, mutect2, varscan2
- FYCO1 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56118189; called by muse, mutect2, varscan2
- FYTTD1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 136/325 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV54085156; called by muse, mutect2, varscan2
- FZD1 | c.794del p.G265Afs*143 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as COSV55308793, COSV55313838; called by mutect2, varscan2
- FZD7 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs185267840, COSV53810975; called by muse, mutect2, varscan2
- GABRA1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 288/528 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50105564; called by muse, mutect2, varscan2
- GABRA5 | c.311G>A p.W104* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV59483471; called by muse, varscan2
- GABRA5 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV59483479; called by muse, varscan2
- GABRR3 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 166/373 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101512359; called by muse, varscan2
- GAL3ST2 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV51951098; called by muse, mutect2
- GALNT18 | c.704G>T p.R235M | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1187655591, COSV57153975; called by muse, mutect2, varscan2
- GALNTL6 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 58/385 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72492396; called by muse, mutect2, varscan2
- GBA | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as CM016030, COSV59169914; called by muse, mutect2, varscan2
- GBE1 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1351314809, COSV70101502; called by muse, mutect2, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs768450027; called by mutect2, pindel, varscan2
- GDF2 | c.1282T>C p.C428R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555209110; called by muse, mutect2, varscan2
- GDF5 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100976829, COSV65499866; called by muse, mutect2, varscan2
- GDF5 | c.297dup p.R100Qfs*6 | Frame Shift Ins (INS) | VAF 55/244 reads (23%) | catalogued as rs761962752; called by mutect2, pindel, varscan2
- GDF7 | c.1126T>C p.Y376H | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV55348213; called by muse, mutect2, varscan2
- GDPD5 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.226); catalogued as rs1173637294, COSV61127450; called by muse, mutect2, varscan2
- GDPGP1 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61575971; called by muse, mutect2, varscan2
- GEMIN5 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 156/527 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs367634594; called by muse, mutect2, varscan2
- GET1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV61555184; called by muse, mutect2, varscan2
- GGT5 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs749872439, COSV54071706; called by muse, mutect2, varscan2
- GIGYF2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770808891, COSV65251940; called by muse, mutect2, varscan2
- GIMAP4 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 117/199 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs183665747, COSV55431678; called by muse, mutect2, varscan2
- GIT2 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs763696895, COSV58077730, COSV58078601; called by muse, mutect2, varscan2
- GLB1L2 | c.1027+1G>A p.X343_splice | Splice Site (SNP) | VAF 26/71 reads (37%) | catalogued as rs1488774244, COSV60279862; called by muse, mutect2, varscan2
- GLRB | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100030167; called by muse, mutect2, varscan2
- GLS2 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV61737998; called by muse, mutect2, varscan2
- GML | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs768613353, COSV55278002, COSV99638337; called by muse, mutect2, varscan2
- GNAI1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV100650634; called by muse, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 56/151 reads (37%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNL2 | c.569+2T>C p.X190_splice | Splice Site (SNP) | VAF 40/94 reads (43%) | catalogued as COSV100895046; called by muse, varscan2
- GNS | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.198); catalogued as rs771940326, COSV50695850; called by muse, mutect2, varscan2
- GOLGA3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 120/208 reads (58%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs201001117; called by muse, mutect2, varscan2
- GOLGB1 | c.3865C>T p.P1289S | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs749615316, COSV61468770; called by muse, mutect2, varscan2
- GORASP2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); catalogued as rs778067597, COSV52201913; called by muse, mutect2, varscan2
- GPATCH8 | c.4402G>A p.A1468T | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV59196562; called by muse, mutect2, varscan2
- GPC1 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as rs901847919, COSV50864774; called by muse, mutect2, varscan2
- GPC6 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764440422, COSV65525082; called by muse, mutect2, varscan2
- GPHB5 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs759641700, COSV58485790; called by muse, mutect2, varscan2
- GPR101 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV53239823; called by muse, mutect2, varscan2
- GPR158 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as rs750773250, COSV66271822; called by muse, mutect2, varscan2
- GPR176 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV100137549; called by muse, mutect2, varscan2
- GPR22 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.664); catalogued as COSV51758820; called by muse, mutect2, varscan2
- GPRASP1 | c.1109T>C p.M370T | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV64356157; called by muse, mutect2, varscan2
- GPRASP1 | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64356158; called by muse, mutect2, varscan2
- GPT | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV52954212; called by muse, mutect2
- GRIN3B | c.1713G>A p.W571* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as rs527469125, COSV52262142; called by muse, mutect2, varscan2
- GRK6 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV62683679, COSV62684313; called by muse, mutect2, varscan2
- GRM1 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV51171747, COSV51300307; called by muse, mutect2, varscan2
- GRM1 | c.2869G>A p.V957I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.191); catalogued as rs1011306026, COSV51221668, COSV51269678; called by muse, mutect2, varscan2
- GRM5 | c.3356C>T p.P1119L (on ENST00000305447 / NM_001143831.2; = p.P1087L on NM_000842.4) | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59595895, COSV59618119; called by muse, mutect2, varscan2
- GRSF1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs368531595; called by muse, mutect2, varscan2
- GTF2A1 | c.1098A>G p.I366M | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV99993572; called by muse, mutect2, varscan2
- GTPBP2 | c.183del p.E62Rfs*11 | Frame Shift Del (DEL) | VAF 59/166 reads (36%) | catalogued as rs756968780; called by mutect2, pindel, varscan2
- H1-10 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61549778; called by muse, mutect2, varscan2
- H2AC6 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as COSV58417113; called by muse, mutect2, varscan2
- HAL | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.198); catalogued as rs780228604, COSV54119384; called by muse, mutect2, varscan2
- HAS3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as rs985994450, COSV54706505; called by muse, mutect2, varscan2
- HAT1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs760798004, COSV51364490; called by muse, mutect2, varscan2
- HAVCR1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 201/369 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs762365419, COSV59401239; called by muse, mutect2, varscan2
- HAX1 | c.827T>C p.F276S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV55178054; called by muse, mutect2, varscan2
- HCAR3 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.68); catalogued as COSV63676616, COSV63676910; called by muse, mutect2, varscan2
- HCFC1 | c.3088A>G p.T1030A | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.931); catalogued as COSV60075471; called by muse, mutect2
- HCST | c.139_140del p.L47Afs*10 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | catalogued as rs1391552111; called by pindel, varscan2
- HDAC5 | c.1871C>A p.A624D | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56820781; called by muse, mutect2, varscan2
- HDAC9 | c.2786C>T p.T929M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1439669052, COSV67773125; called by muse, varscan2
- HDHD2 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV56076540; called by muse, varscan2
- HDLBP | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as rs750987672, COSV60496268; called by muse, mutect2, varscan2
- HECTD4 | c.6512A>G p.Q2171R | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1316368488, COSV66396651; called by muse, mutect2, varscan2
- HECW1 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV67836351; called by muse, mutect2, varscan2
- HELQ | c.3063G>T p.E1021D | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV55026610; called by muse, mutect2, varscan2
- HELZ2 | c.5089G>A p.A1697T (on ENST00000467148 / NM_001037335.2; = p.A1128T on NM_033405.3) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1293935238, COSV71296555; called by muse, mutect2, varscan2
- HELZ2 | c.4052G>A p.C1351Y (on ENST00000467148 / NM_001037335.2; = p.C782Y on NM_033405.3) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as COSV71295974; called by muse, mutect2
- HEPHL1 | c.2156G>A p.C719Y | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59894543; called by muse, mutect2, varscan2
- HGS | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.519); catalogued as rs935114414, COSV61269454; called by muse, mutect2, varscan2
- HHAT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 105/260 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs143700139; called by muse, mutect2, varscan2
- HHAT | c.1392C>T p.G464= | Splice Region (SNP) | VAF 27/138 reads (20%) | catalogued as COSV54805076; called by muse, mutect2, varscan2
- HINFP | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV63432445; called by muse, mutect2, varscan2
- HLA-DPB1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69602413; called by muse, mutect2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | catalogued as rs779589617; called by mutect2, varscan2
- HNRNPH3 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 61/148 reads (41%) | catalogued as rs867423663, COSV56262708; called by muse, mutect2, varscan2
- HNRNPLL | c.295T>A p.F99I | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55368681; called by muse, mutect2, varscan2
- HNRNPUL2 | c.673C>A p.R225S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV53666408; called by muse, mutect2, varscan2
- HOOK3 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56885754; called by muse, mutect2, varscan2
- HOXC10 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 78/127 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1381948513, COSV57726814; called by muse, mutect2, varscan2
- HPR | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 247/598 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs182745400; called by muse, mutect2, varscan2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs764867254; called by mutect2, pindel, varscan2
- HRH2 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 133/245 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51575372; called by muse, varscan2
- HRH2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51575390; called by muse, varscan2
- HRNR | c.7990C>T p.H2664Y | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1306437409, COSV99056794; called by muse, mutect2, varscan2
- HS2ST1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs774505983, COSV63351294; called by muse, mutect2, varscan2
- HS6ST3 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs747013290, COSV104428399, COSV65015187; called by muse, mutect2, varscan2
- HSF4 | c.1014C>A p.S338R (on ENST00000521374 / NM_001040667.3; = p.S308R on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as COSV50458676; called by muse, mutect2, varscan2
- HSPA14 | c.284del p.N95Mfs*8 | Frame Shift Del (DEL) | VAF 49/111 reads (44%) | catalogued as rs760011797; called by mutect2, pindel, varscan2
- HSPBAP1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 138/329 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.612); catalogued as rs1438614655, COSV60243187; called by muse, mutect2, varscan2
- HTR1A | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 88/332 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as rs557845021, COSV60500946; called by muse, mutect2, varscan2
- HTR1A | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222021133, COSV60500236; called by muse, mutect2, varscan2
- HTR1E | c.801del p.F268Sfs*5 | Frame Shift Del (DEL) | VAF 55/152 reads (36%) | catalogued as rs753568078, COSV59508996, COSV59509296; called by mutect2, pindel, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 63/168 reads (38%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTT | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61866322; called by muse, mutect2
- HTT | c.4754T>C p.L1585S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV61866348; called by muse, mutect2, varscan2
- HTT | c.4917G>T p.E1639D | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV61866356; called by muse, mutect2, varscan2
- HUWE1 | c.9275A>G p.E3092G | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53357437; called by muse, mutect2, varscan2
- HVCN1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 85/122 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748997855, COSV54373293; called by muse, mutect2, varscan2
- HYAL1 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV56498873; called by muse, mutect2, varscan2
- HYDIN | c.6253C>T p.R2085W | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752398645, COSV59249432; called by muse, mutect2, varscan2
- HYI | c.839A>T p.D280V (on ENST00000372434 / NM_001330526.2; = p.D255V on NM_001190880.2) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV65095169; called by muse, mutect2, varscan2
- IBSP | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV56896632; called by muse, mutect2, varscan2
- IDH1 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV61633720; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel
- IFI16 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV55537652, COSV99857240; called by muse, mutect2, varscan2
- IFIH1 | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV55128746; called by muse, mutect2, varscan2
- IFT122 | c.1939C>T p.R647C (on ENST00000348417 / NM_052989.3; = p.R588C on NM_018262.4) | Missense Mutation (SNP) | VAF 165/415 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs761881670, COSV56205886; called by muse, mutect2, varscan2
- IFT80 | c.36G>A p.K12= | Splice Region (SNP) | VAF 51/156 reads (33%) | catalogued as rs764052178, COSV58452554; called by muse, mutect2, varscan2
- IGDCC3 | c.1562-1G>A p.X521_splice | Splice Site (SNP) | VAF 15/64 reads (23%) | catalogued as COSV60078972; called by muse, mutect2, varscan2
- IGF2R | c.3949dup p.D1317Gfs*5 | Frame Shift Ins (INS) | VAF 30/100 reads (30%) | catalogued as rs760021495; called by mutect2, varscan2
- IGF2R | c.4066C>T p.R1356* | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | catalogued as rs750646803, COSV63631315; called by muse, mutect2, varscan2
- IGFALS | c.1640T>C p.L547P | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99236699; called by muse, mutect2, varscan2
- IGFBP6 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV56857760; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1187269216; called by muse, mutect2, varscan2
- IKBKE | c.1042del p.R348Dfs*32 | Frame Shift Del (DEL) | VAF 33/74 reads (45%) | catalogued as COSV65625022; called by mutect2, pindel, varscan2
- IKZF2 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59581662; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 144/212 reads (68%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV56284076; called by muse, mutect2, varscan2
- IL21R | c.63del p.D22Tfs*37 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as COSV100560452; called by mutect2, pindel, varscan2
- ILKAP | c.837G>A p.R279= | Splice Region (SNP) | VAF 21/48 reads (44%) | catalogued as COSV54519335; called by muse, mutect2, varscan2
- INCENP | c.2357C>T p.A786V (on ENST00000394818 / NM_001040694.2; = p.A782V on NM_020238.3) | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53919106; called by muse, mutect2, varscan2
2,072 further variants in this file (1,440 protein-altering or splice-affecting, 591 silent, 41 other) are not listed here.
